Gene-level copy-number profile of tumor specimen MP2PRT-PAUEZG-TMP1-A from MP2PRT case MP2PRT-PAUEZG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.3 years (3,040 days).
Specimen MP2PRT-PAUEZG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e705bb00-a3bd-499c-8853-5f8330505779.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUEZG-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,739 have no estimate.
https://portal.gdc.cancer.gov/files/30cf55b3-acd9-48af-a6e1-9ec0113006ff

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 372; copy number 2: 55,524; copy number 3: 2,238; copy number 4: 737.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,209,873–90,221,384, 2 genes: IGKV1D-43, IGKV1D-8.
- chr8:80,967,810–81,112,068, 3 genes: PAG1, AC022778.1, AC079209.2.
- chr9:41,979,352–42,189,887, 3 genes: CR788268.1, RN7SL343P, SPATA31A6.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–1): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–1): IGHV3-43.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 372. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
